FM case AD73 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/65cbf41e-e791-40ae-a7b3-908b66ef82dd

Female, 52.7 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast. Tumor nuclei on the sequenced sample's slide: 100% (pathologist estimate recorded by GDC). Sample type: Tumor.
